National Lung Screening Trial (NLST) participant 208735 — screening results, CT findings and lung cancer
Open-access record from the public subset of National Lung Screening Trial clinical data distributed by the NCI Imaging Data Commons (release v24, collection nlst). NLST enrolled current and former heavy smokers aged 55–74 in 2002–2004 and randomised them to three annual screens (T0, T1, T2) with low-dose CT or chest radiography, with follow-up through 2009. Coded values are written out from the NLST data dictionaries; day counts are days from randomisation.
https://doi.org/10.7937/TCIA.HMQ8-J677

Participant
Age at randomisation: 57 years; Gender: male; Race: White; Cigarette smoking status at randomisation: former smoker (to be eligible, former smokers had quit within the previous 15 years); Enrolled through an American College of Radiology Imaging Network (ACRIN) centre (from the participant ID range).

Screening results (official result of each annual screen after comparison with prior images; this participant has CT screening exam records, so these are low-dose CT screens)
- T0 (day 0): Positive, change unspecified: nodule(s) >= 4 mm or enlarging nodule(s), mass(es), or other non-specific abnormalities suspicious for lung cancer. Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 60 mA, display field of view 35 cm, reconstruction filter GE Bone / GE Standard.
- T1 (day 342): Positive, no significant change: stable abnormalities potentially related to lung cancer, unchanged since the prior screening exam. Isolation read, before comparison with prior images: positive (nodule(s) >= 4 mm, mass or other suspicious abnormality). Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 120 mA, display field of view 36 cm, reconstruction filter GE Bone / GE Standard.
- T2: No screening result: Not Expected - Death in screening window.

Abnormalities recorded by the reading radiologist on the CT screens (8 abnormalities; numbered within each screening year; size, margins, attenuation and location were collected only for non-calcified nodules or masses of at least 4 mm; interval-change items come from the comparison read)
- T0 abnormality 1: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the right upper lobe; longest diameter 7 mm, longest perpendicular diameter 6 mm; margins smooth; predominant attenuation soft tissue; greatest diameter on CT slice 75.
- T0 abnormality 2: Benign lung nodule(s) (benign calcification).
- T0 abnormality 3: Reticular/reticulonodular opacities, honeycombing, fibrosis, scar.
- T1 abnormality 1: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the right upper lobe; longest diameter 9 mm, longest perpendicular diameter 6 mm; margins smooth; predominant attenuation soft tissue; greatest diameter on CT slice 66; pre-existing on earlier images (earliest visible day 0); no interval growth; no suspicious change in attenuation.
- T1 abnormality 2: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the right lower lobe; longest diameter 10 mm, longest perpendicular diameter 9 mm; margins spiculated (stellate); predominant attenuation soft tissue; greatest diameter on CT slice 126; pre-existing on earlier images (earliest visible day 0); no interval growth; no suspicious change in attenuation.
- T1 abnormality 3: Emphysema.
- T1 abnormality 4: Reticular/reticulonodular opacities, honeycombing, fibrosis, scar; pre-existing on earlier images (earliest visible day 0); interval change does not warrant further investigation.
- T1 abnormality 5: Significant cardiovascular abnormality.

Lung cancer (1 primary lung cancer record; the first confirmed lung cancer followed a positive screen; study year of the first confirmed lung cancer: T1; the diagnosis is linked to a positive screen through the trial's diagnostic-procedure linking algorithm)
1. First primary lung cancer, diagnosed day 674, study year T1. Site: upper lobe of lung (ICD-O-3 C34.1), determined from cytology. Primary tumour location: left upper lobe. Histology: adenocarcinoma, NOS (ICD-O-3 8140/3). Tumour size on pathology: 50 mm. AJCC 6th edition staging: stage IV (best stage, from pathologic TNM); clinical TX N2 M1 (stage IV); pathologic T4 N2 M1 (stage IV). AJCC 7th edition staging: stage IV; clinical T4 N2 M1b; pathologic T4 NX M1b. Summary stage: distant.

Follow-up
Last known free of lung cancer: day 674 (for ACRIN participants with lung cancer this field holds the diagnosis date).
